CPTAC case 22CO006 — Colon — Adenomas and Adenocarcinomas (CPTAC-2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon.
https://portal.gdc.cancer.gov/cases/57ba7281-a126-4b47-82fa-c59e4135421d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Prior malignancy: no.

Biospecimens (2 samples)
- Sample 3487b5c2-1dce-4e1c-bb84-30e8f2: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
- Sample 4d86cf19-8d5b-46b5-ab4c-ace0b2: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
